CCDI case PBBKFX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cf20738e-d24d-483d-850a-3c460a4f99ff

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Oligoastrocytoma: ICD-O-3 morphology code: 9382/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 10.4 years (3,792 days).

Biospecimens (3 samples)
- Sample 0DAOS6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAOS7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAOS8: Tissue type: Normal; Specimen type: Solid Tissue.
